Somatic mutation profile of tumor specimen TCGA-EK-A2RN-01A (aliquot TCGA-EK-A2RN-01A-12D-A20U-09) from TCGA case TCGA-EK-A2RN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 45.1 years (16,487 days).
Specimen TCGA-EK-A2RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5d28c2a-fbaa-4230-9830-381891ba7524.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RN-10A (Blood Derived Normal), aliquot TCGA-EK-A2RN-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1ba904f-b650-42b1-aea1-7b75abe5bbaf

The open-access MAF lists 172 somatic variants for this specimen: 125 protein-altering or splice-affecting, 39 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 39, Nonsense Mutation 7, RNA 3, Intron 2, Splice Site 2, 5'Flank 2, 3'UTR 1, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NDP | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs137852220, CM930511, CM963076, COSV65203366; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 43/90 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11687C>T p.S3896F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773960552, COSV71283391; called by muse, mutect2, varscan2
- ABCC9 | c.1323C>T p.I441= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53962726; called by muse, mutect2
- ABCG2 | c.1921C>T p.L641F | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as COSV52943040, COSV52948200; called by muse, mutect2
- ACE2 | c.1854C>G p.I618M | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99382548; called by muse, mutect2
- ADAD2 | c.932G>A p.G311D (on ENST00000315906 / NM_001145400.2; = p.G393D on NM_139174.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV99235083; called by muse, mutect2
- ADAM7 | c.53-1G>A p.X18_splice | Splice Site (SNP) | VAF 52/84 reads (62%) | catalogued as rs778043558, COSV51535084; called by muse, mutect2, varscan2
- AKAP7 | c.868G>C p.E290Q (on ENST00000431975 / NM_016377.4; = p.E23Q on NM_004842.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV53833497; called by muse, mutect2, varscan2
- ANO5 | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.52); catalogued as rs1326315048, COSV100202115, COSV61082087; called by muse, mutect2, varscan2
- AOC1 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV62866851; called by muse, mutect2, varscan2
- API5 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1341381468, COSV66632439; called by muse, mutect2, varscan2
- ARMH4 | c.1268A>T p.E423V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV50761627; called by muse, mutect2, varscan2
- ATP11C | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as COSV65266132; called by mutect2, varscan2
- BCLAF3 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61413077; called by muse, mutect2, varscan2
- C9orf131 | c.1203G>C p.E401D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56609590; called by muse, mutect2, varscan2
- CACNB3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56397153; called by muse, mutect2, varscan2
- CAPN6 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as rs746415109, COSV60693866, COSV60695734; called by muse, mutect2, varscan2
- CAPN9 | c.1508A>C p.D503A | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55230492; called by muse, mutect2, varscan2
- CCNA1 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55219900; called by muse, mutect2, varscan2
- CEP170B | c.1144G>A p.G382R (on ENST00000453495; = p.G311R on NM_015005.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.948); catalogued as rs375604191, COSV69025195; called by muse, mutect2, varscan2
- CHD3 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV57872526; called by muse, mutect2, varscan2
- CHD5 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52407559; called by muse, mutect2, varscan2
- CIAO2B | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs1207559843, COSV57696161, COSV57696611; called by muse, mutect2, varscan2
- CNTN1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636194; called by mutect2, varscan2
- CNTNAP5 | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70472942; called by muse, mutect2, varscan2
- COL11A1 | c.5360A>C p.D1787A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62173015; called by muse, mutect2, varscan2
- CRBN | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs758183266, COSV51639871; called by muse, mutect2, varscan2
- CREB3L4 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55209213; called by muse, mutect2, varscan2
- CTSS | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64565874; called by muse, mutect2
- CYP7B1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV59582508, COSV59589444; called by muse, mutect2, varscan2
- DEFB104A | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV58629618; called by mutect2, varscan2
- DLG2 | c.217G>A p.E73K (on ENST00000650630 / NM_001351274.2; = p.E36K on NM_001142699.3) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); catalogued as COSV65825365; called by muse, mutect2, varscan2
- DNAJC13 | c.6335C>T p.A2112V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV53445702; called by muse, mutect2, varscan2
- DSN1 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV101041126, COSV65518554; called by muse, mutect2, varscan2
- ECHDC2 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.383); catalogued as COSV64300117; called by muse, mutect2, varscan2
- EEF1B2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.035); catalogued as COSV51907959; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2452C>G p.P818A | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100348771, COSV57514515; called by muse, mutect2, varscan2
- ENPP2 | c.1921G>C p.E641Q (on ENST00000075322 / NM_001040092.3; = p.E693Q on NM_006209.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV50010000; called by muse, mutect2
- EPHA8 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51262654; called by muse, mutect2, varscan2
- EXPH5 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372482068, COSV56198923; called by mutect2, varscan2
- FAM83H | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66353429, COSV66354718; called by muse, varscan2
- FAM9A | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1234915071, COSV101121301; called by muse, mutect2
- FBLN1 | c.2111G>C p.*704Sext*38 | Nonstop Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59936248; called by muse, mutect2, varscan2
- FBXL18 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66665171; called by muse, mutect2, varscan2
- FBXL8 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs375713237, COSV50456585; called by muse, mutect2, varscan2
- FLOT2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV67528813; called by muse, mutect2, varscan2
- FRAS1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs576372683, COSV53589313, COSV53611112; called by muse, mutect2, varscan2
- FRMPD3 | c.3895G>A p.E1299K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1429719966, COSV52186514, COSV99345662; called by muse, mutect2
- FZD2 | c.801G>C p.L267F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as COSV59528104; called by muse, mutect2, varscan2
- FZR1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1446224791, COSV58050230; called by muse, mutect2, varscan2
- GAST | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV61475417; called by mutect2, varscan2
- GNAS | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV55671248; called by muse, mutect2, varscan2
- GNL2 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as rs374278862; called by muse, mutect2, varscan2
- GRIP2 | c.2606G>A p.R869H (on ENST00000619221; = p.R772H on NM_001080423.4) | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs374577398, COSV56123112; called by muse, mutect2, varscan2
- GRM5 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776804851, COSV59590843; called by muse, mutect2, varscan2
- HACE1 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53499212; called by muse, mutect2, varscan2
- HCLS1 | c.158A>C p.N53T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV58854372; called by muse, mutect2, varscan2
- HMMR | c.1683-1G>A p.X561_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as rs1487487470, COSV62373822; called by muse, mutect2, varscan2
- KANK1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV63209576; called by muse, mutect2
- KIAA1549L | c.4645G>A p.E1549K (on ENST00000321505; = p.E1846K on NM_012194.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754661833, COSV58581735; called by mutect2, varscan2
- KIF4B | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV70527837; called by muse, mutect2, varscan2
- KLK2 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs536878458, COSV57568224; called by muse, mutect2, varscan2
- LAMC3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs1162613016, COSV63088593; called by muse, mutect2, varscan2
- LIMD1 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56265902; called by muse, mutect2, varscan2
- LIN7C | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV53414601, COSV53414782; called by muse, mutect2, varscan2
- MAGEC3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV53578748; called by muse, mutect2, varscan2
- MAGEL2 | c.2250G>A p.M750I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV58565879; called by muse, mutect2, varscan2
- MAL2 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV52659912, COSV99411033; called by muse, mutect2, varscan2
- MASTL | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV60909469; called by muse, mutect2, varscan2
- MBTPS1 | c.2006G>A p.R669K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs897628296, COSV58569353; called by muse, mutect2, varscan2
- MSANTD2 | c.1054G>C p.E352Q (on ENST00000374979 / NM_001308027.2; = p.E300Q on NM_024631.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53447411; called by muse, mutect2
- MSANTD4 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV57285165; called by muse, mutect2, varscan2
- MYBPHL | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV64062121, COSV64062151; called by muse, mutect2, varscan2
- MYO15A | c.9401G>A p.R3134Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373695303; called by muse, mutect2, varscan2
- N4BP2L1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.637); catalogued as COSV58412150; called by muse, mutect2, varscan2
- NAV3 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs572701178, COSV57061979; called by muse, mutect2, varscan2
- NKRF | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV58660698; called by muse, mutect2, varscan2
- NOL8 | c.3138C>G p.F1046L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62634123; called by muse, mutect2, varscan2
- NRK | c.1826T>C p.L609P | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1326510259, COSV54591790; called by muse, mutect2, varscan2
- NTRK2 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV52853917; called by muse, mutect2, varscan2
- NYNRIN | c.3569C>G p.S1190* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV66841155; called by muse, mutect2, varscan2
- ODF1 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.773); catalogued as rs763645116, COSV53431569, COSV53433018; called by muse, mutect2, varscan2
- OR4E2 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57731367; called by muse, mutect2
- OR8G5 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV58380101, COSV58383992; called by muse, mutect2, varscan2
- OR8H2 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV57943148; called by muse, mutect2, varscan2
- PATL1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55687851; called by muse, mutect2, varscan2
- PCDH17 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100932127, COSV64971710; called by muse, mutect2
- PCLO | c.5332G>A p.E1778K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV61616370, COSV61617215; called by muse, mutect2, varscan2
- POLA1 | c.2300A>G p.Q767R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66883693; called by muse, mutect2, varscan2
- PRAG1 | c.2410G>A p.V804M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.342); catalogued as rs768156378, COSV58157352; called by muse, mutect2, varscan2
- PRPF40A | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.969); catalogued as COSV62956639; called by muse, mutect2, varscan2
- PRPS2 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV66179234, COSV66180136; called by muse, mutect2, varscan2
- QSOX2 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV62393377; called by muse, mutect2, varscan2
- RAD21 | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV52056181; called by muse, mutect2, varscan2
- RGL2 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.087); catalogued as COSV69915816, COSV69916341; called by muse, mutect2, varscan2
- RTKN2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV65679737; called by muse, mutect2, varscan2
- RUNX1T1 | c.496C>T p.H166Y (on ENST00000265814 / NM_001198628.1; = p.H139Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868452433, COSV56137692, COSV99752362; called by muse, mutect2, varscan2
- SCN1A | c.2650G>A p.G884S (on ENST00000303395 / NM_001202435.3; = p.G873S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1253956567, COSV57660181; called by muse, mutect2, varscan2
- SDK2 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs756850845, COSV66181335; called by muse, mutect2, varscan2
- SELENBP1 | c.1374G>T p.E458D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV64372951, COSV64373229; called by muse, mutect2, varscan2
- SFXN1 | c.671A>C p.Q224P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as COSV58491939; called by muse, mutect2, varscan2
- SMCHD1 | c.3413C>T p.A1138V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV55251677; called by muse, mutect2, varscan2
- SMCHD1 | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55251697; called by muse, mutect2, varscan2
- SOWAHD | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100673112; called by muse, mutect2
- SPP2 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV51444423; called by muse, mutect2, varscan2
- SRGAP2 | c.1628G>C p.R543T (on ENST00000624873 / NM_001170637.4; = p.R544T on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99832402; called by mutect2, varscan2
- STAT2 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.889); catalogued as COSV58474269; called by muse, mutect2, varscan2
- TAAR5 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV57798467, COSV57798798; called by muse, mutect2, varscan2
- TAB3 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV55834369; called by muse, mutect2, varscan2
- TAF1L | c.3604G>C p.E1202Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99643959; called by muse, mutect2
- TFDP3 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs767188782, COSV59535811; called by muse, mutect2, varscan2
- TIAM1 | c.2930C>T p.A977V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs764569624, COSV54537784; called by muse, mutect2, varscan2
- TRA2B | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV52024691; called by muse, mutect2, varscan2
- TRAV12-1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs1438353385; called by muse, mutect2, varscan2
- TRBV4-2 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs775198138; called by muse, mutect2
- TRMT2A | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52812373; called by muse, mutect2, varscan2
- TTN | c.40489G>A p.E13497K (on ENST00000591111; = p.E6073K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | PolyPhen benign (0.359); catalogued as COSV59889495; called by muse, mutect2, varscan2
- TTYH1 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); catalogued as rs752829139, COSV56609665; called by mutect2, varscan2
- VEPH1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV62875961; called by muse, mutect2, varscan2
- VGLL1 | c.370T>A p.S124T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV65702893; called by muse, mutect2, varscan2
- VSIG1 | c.444A>C p.Q148H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.28); catalogued as COSV54257663; called by muse, mutect2, varscan2
- ZNF37A | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs371302765; called by muse, mutect2
- TTYH1 | c.225del p.E76Sfs*76 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.687C>T p.I229= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs757399520, COSV55438940, COSV55449825; called by muse, mutect2, varscan2
- ADGRL4 | c.231C>T p.N77= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1460918655, COSV66059247; called by muse, mutect2, varscan2
- ADH4 | c.1020C>T p.D340= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55500069; called by muse, mutect2, varscan2
- ANAPC15 | c.132C>T p.I44= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs539199138, COSV56190774; called by muse, mutect2, varscan2
- ARHGEF6 | c.1671C>A p.S557= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV51687547; called by muse, mutect2, varscan2
- CDH10 | c.786C>T p.V262= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs1419600429, COSV52570104; called by muse, mutect2, varscan2
- CFAP74 | c.192G>A p.K64= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV99573849; called by muse, mutect2
- COG4 | c.1899C>T p.S633= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs554213038, COSV55367643; called by muse, mutect2, varscan2
- COL4A5 | c.4653C>A p.P1551= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV60356163; called by muse, mutect2, varscan2
- DECR1 | c.57C>T p.L19= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV55166738; called by muse, mutect2, varscan2
- GGT5 | c.1299G>A p.E433= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs752530955, COSV99571260; called by mutect2, varscan2
- IFT81 | c.36C>G p.L12= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV54360517; called by muse, mutect2, varscan2
- ILKAP | c.69G>A p.Q23= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV54517386; called by muse, mutect2, varscan2
- ITIH6 | c.1992G>A p.V664= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV54486498; called by muse, mutect2, varscan2
- KCNQ2 | c.435C>T p.I145= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV60431842; called by muse, mutect2, varscan2
- KDM3B | c.4707G>A p.V1569= | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV58688013; called by muse, mutect2, varscan2
- KIAA1109 | c.1968C>G p.V656= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99145817; called by muse, mutect2, varscan2
- MATN1 | c.210G>A p.S70= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs139060426; called by muse, mutect2, varscan2
- MCHR1 | c.1149C>T p.L383= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs199767344, COSV50760327; called by muse, mutect2, varscan2
- NPM2 | c.42G>C p.V14= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs372304710; called by muse, mutect2, varscan2
- NUP188 | c.2064C>T p.T688= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV101001451, COSV65360307; called by muse, mutect2, varscan2
- ORM1 | c.156C>T p.N52= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs551088472, COSV52278388; called by muse, mutect2, varscan2
- PCDHA4 | c.687C>T p.L229= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV63538867; called by muse, mutect2, varscan2
- PCDHB8 | c.1935C>G p.V645= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs537745447, COSV50753542; called by muse, mutect2, varscan2
- PCDHGB5 | c.1623C>T p.N541= | Silent (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- PCNT | c.5151G>A p.L1717= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1457259804, COSV64025073; called by muse, mutect2, varscan2
- PGAP2 | c.70C>T p.L24= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99544065; called by muse, mutect2, varscan2
- PLIN5 | c.588C>T p.G196= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV67850357; called by muse, mutect2, varscan2
- PRDM9 | c.1299G>T p.G433= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs752410339, COSV57002510; called by muse, mutect2, varscan2
- PTGS2 | c.511A>C p.R171= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV66568283; called by muse, mutect2, varscan2
- SLC4A1 | c.420C>T p.I140= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV52258347; called by muse, mutect2, varscan2
- SLC6A17 | c.1029G>A p.T343= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs749859472, COSV58991334; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A14 | c.873C>T p.A291= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51577932; called by muse, mutect2, varscan2
- TAS2R1 | c.678G>A p.A226= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs140696180; called by muse, mutect2, varscan2
- TSC2 | c.3618C>T p.T1206= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1057522260, COSV54756110; called by muse, mutect2, varscan2
- UGGT1 | c.1995C>T p.F665= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1196743550, COSV52132403, COSV52133834; called by mutect2, varscan2
- ZNF787 | c.579C>T p.L193= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV54417598; called by muse, varscan2
- ZNF813 | c.442C>T p.L148= | Silent (SNP) | VAF 59/96 reads (61%) | catalogued as COSV67175682, COSV67177534; called by muse, mutect2, varscan2
- ZSWIM8 | c.4515G>A p.L1505= (on ENST00000605216 / NM_001242487.2; = p.L1510= on NM_015037.3) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100013624; called by muse, mutect2, varscan2
- ACACA | c.339-14344G>A | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822869 C>T | 5'Flank (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- AL353804.4 | chrX:73823054 C>G | 5'Flank (SNP) | VAF 10/86 reads (12%) | catalogued as rs1556544888; called by muse, mutect2, varscan2
- MIR509-3 | n.53C>T | RNA (SNP) | VAF 18/105 reads (17%) | catalogued as rs781816035; called by muse, mutect2, varscan2
- MIR890 | n.67A>C | RNA (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2670G>C | Intron (SNP) | VAF 8/66 reads (12%) | catalogued as COSV52740112; called by muse, mutect2, varscan2
- PPM1M | c.*344C>T | 3'UTR (SNP) | VAF 40/56 reads (71%) | catalogued as COSV99626018; called by muse, mutect2, varscan2
- SSPOP | n.12044G>A | RNA (SNP) | VAF 7/33 reads (21%) | catalogued as rs1477265201, COSV65127081; called by muse, mutect2, varscan2
